MMRF case MMRF_1860 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ccc6ebdb-618f-4a58-9bc3-c581868f6b29

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.1 years (16,843 days); ISS stage: II; Days to last known disease status: 1,012 days (2.8 years); Days to last follow up: 1,012 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Doxorubicin + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 257 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 256 days; Days to treatment end: 256 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 258 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 2): M Protein 3.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 63 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 10.3 g/dL; Glucose 5.39 mmol/L.
- Day 95 (ECOG 1): M Protein 1.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.103 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.593 mg/dL; Immunoglobulin G 2.68 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.26 µg/mL; Lactate Dehydrogenase 7.47 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.05 mmol/L; Albumin 30 g/L; Total Protein 5.1 g/dL; Glucose 6.6 mmol/L.
- Day 175 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 7.43 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 287 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.38 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 9.79 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 6.77 mmol/L.
- Day 344 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 435 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.81 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 6.8 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 5.5 mmol/L.
- Day 529 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 1.13 g/L; Beta 2 Microglobulin 2.29 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 634 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 6.11 mmol/L.
- Day 725 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.
- Day 823 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 921 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.94 mmol/L.
- Day 1,012 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -16: Weight: 91 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1860_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1860_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
